HCMI case HCM-CSHL-0376-D37 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0e9a9e97-f0bf-4f4a-84cc-73eccfc627b1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1942; Vital status: Alive.

Diagnoses (1)
1. Tubulovillous adenoma, NOS: ICD-O-3 morphology code: 8263/0; ICD-10 code: D37.4; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Ascending colon; Classification of tumor: Premalignant; Age at diagnosis: 75.4 years (27,551 days); Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 78 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (2 entries)
- Days to follow up: 400 days (1.1 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 170.

Molecular and laboratory tests
- Test (Microsatellite Analysis): Negative.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.
- Timepoint category: Initial Diagnosis; Weight: 106.14 kg; Height: 177.8 cm; BMI: 34.
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Days to comorbidity: 78 days; Days to risk factor: 78 days; Risk factors: Colon Polyps.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0376-D37-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0376-D37-31A: Sample type: Neoplasms of Uncertain and Unknown Behavior; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0376-D37-31A-01-S1-HE: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 4.
  Slide HCM-CSHL-0376-D37-31A-01-S2-HE: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 4.
- Sample HCM-CSHL-0376-D37-85P: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: 3D Organoid; Preservation method: Frozen.
